Somatic mutation profile of tumor specimen TCGA-UC-A7PI-01A (aliquot TCGA-UC-A7PI-01A-11D-A42O-09) from TCGA case TCGA-UC-A7PI, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endocervix; FIGO stage: Stage IB1; Tumor grade: G1; Age at diagnosis: 45.0 years (16,427 days).
Specimen TCGA-UC-A7PI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 29c08558-0648-4acc-ba8c-8383a3a59ff0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-UC-A7PI-10A (Blood Derived Normal), aliquot TCGA-UC-A7PI-10A-01D-A42R-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6e0cdb42-d3ad-41ad-8467-23e424b620ae

The open-access MAF lists 57 somatic variants for this specimen: 41 protein-altering or splice-affecting, 15 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 15, Nonsense Mutation 2, Translation Start Site 1, Frame Shift Del 1, Splice Site 1, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CNTNAP2 | c.3577G>A p.A1193T | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.81); catalogued as rs751491210, COSV100664288; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- KRAS | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 471/520 reads (91%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as rs121913527, COSV55501778, COSV55541748, COSV55727828; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- ADAM33 | c.1801G>A p.G601S | Missense Mutation (SNP) | VAF 28/40 reads (70%) | SIFT tolerated (0.14); PolyPhen benign (0.39); catalogued as COSV100597762; called by muse, mutect2, varscan2
- ADGRG4 | c.812C>G p.S271C | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.536); catalogued as COSV99794922; called by muse, mutect2, varscan2
- AGO1 | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as rs1196584082, COSV100940788; called by mutect2, varscan2
- AP2A1 | c.2927A>G p.Q976R | Missense Mutation (SNP) | VAF 74/146 reads (51%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.893); catalogued as COSV100571054; called by muse, mutect2, varscan2
- ARAP3 | c.2996G>A p.R999H | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.631); catalogued as rs762292586, COSV99499483; called by muse, mutect2, varscan2
- BLK | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 23/48 reads (48%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.558); catalogued as COSV99377004; called by muse, mutect2, varscan2
- CACNA1C | c.5091G>T p.R1697S | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV100217112; called by muse, mutect2, varscan2
- CELSR3 | c.9689C>T p.S3230L | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs1255119007, COSV99373025; called by muse, mutect2, varscan2
- CHD9 | c.6601G>A p.E2201K | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT tolerated (0.22); PolyPhen benign (0.023); catalogued as rs778083494, COSV99528889; called by muse, mutect2, varscan2
- COL19A1 | c.2947G>T p.G983C | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749516621, COSV100505657; called by muse, mutect2, varscan2
- DPP9 | c.932A>G p.K311R (on ENST00000598800; = p.K340R on NM_139159.5) | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.39); PolyPhen benign (0.324); catalogued as rs762557101, COSV99505849; called by muse, mutect2, varscan2
- DRP2 | c.302C>G p.S101* | Nonsense Mutation (SNP) | VAF 58/121 reads (48%) | catalogued as COSV100871849; called by muse, mutect2, varscan2
- EDNRB | c.1222-1G>A p.X408_splice (on ENST00000377211 / NM_001201397.1; = p.X318_splice on NM_000115.5) | Splice Site (SNP) | VAF 26/63 reads (41%) | catalogued as COSV100526423; called by muse, mutect2, varscan2
- GPM6B | c.249G>C p.V83= | Splice Region (SNP) | VAF 48/104 reads (46%) | catalogued as COSV100366106; called by muse, mutect2, varscan2
- ING1 | c.971C>T p.A324V | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT tolerated (0.12); PolyPhen benign (0.108); catalogued as COSV58167182; called by muse, mutect2, varscan2
- KANSL1 | c.238G>A p.A80T | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as rs772056723, COSV99294258; called by muse, mutect2, varscan2
- KCNRG | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100078234; called by muse, mutect2, varscan2
- LRCH1 | c.47C>T p.S16L | Missense Mutation (SNP) | VAF 66/140 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV60849777; called by muse, mutect2, varscan2
- LRRC32 | c.134C>T p.S45L | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs745971810, COSV52636071; called by muse, varscan2
- MOK | c.811G>A p.D271N | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.679); catalogued as rs1197414796, COSV51963136; called by muse, mutect2, varscan2
- MYRIP | c.2167C>T p.R723C | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.872); catalogued as rs145458813; called by mutect2, varscan2
- NUAK1 | c.1891C>T p.R631W | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.859); catalogued as rs552453023, COSV99776792; called by muse, mutect2, varscan2
- NUBPL | c.680G>C p.R227T | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV99809253; called by muse, mutect2, varscan2
- NUP210L | c.4345A>G p.M1449V | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99667563; called by muse, mutect2, varscan2
- OR2L8 | c.905G>A p.R302Q | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.06); catalogued as rs377182490, COSV61725763; called by muse, mutect2, varscan2
- PAPSS1 | c.274C>T p.R92C | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1190978842, COSV54488263; called by muse, mutect2, varscan2
- PASK | c.1408G>C p.E470Q | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99298973, COSV99299665; called by muse, mutect2, varscan2
- PCDH9 | c.1609C>T p.R537* | Nonsense Mutation (SNP) | VAF 18/54 reads (33%) | catalogued as rs1276928919, COSV60596631; called by muse, mutect2, varscan2
- PITPNM2 | c.2530G>A p.G844S | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV99758540; called by muse, mutect2, varscan2
- POTEM | c.1003G>A p.D335N | Missense Mutation (SNP) | VAF 26/178 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66935800; called by muse, mutect2, varscan2
- PTEN | c.59del p.G20Dfs*4 | Frame Shift Del (DEL) | VAF 14/32 reads (44%) | catalogued as COSV64299322, COSV64301292; called by mutect2, pindel, varscan2
- RNF135 | c.1007G>A p.R336H | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs140592050; called by muse, mutect2, varscan2
- SRP68 | c.703C>G p.Q235E | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.647); catalogued as COSV100326013; called by muse, mutect2, varscan2
- TRPM2 | c.1708G>T p.G570W | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100308417; called by muse, mutect2, varscan2
- WNT5A | c.1055C>T p.T352M | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.502); catalogued as rs755298573, COSV52837872; called by muse, mutect2, varscan2
- XRCC1 | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.043); catalogued as rs370972033; called by muse, mutect2, varscan2
- ZNF468 | c.573G>T p.K191N | Missense Mutation (SNP) | VAF 57/129 reads (44%) | SIFT tolerated (0.58); PolyPhen benign (0.005); catalogued as COSV99700441; called by muse, mutect2, varscan2
- ZNF746 | c.1798C>T p.P600S | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.057); catalogued as COSV100502397; called by muse, mutect2
- WASHC2C | c.2099C>A p.S700Y | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- AMZ1 | c.75C>T p.D25= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as rs200327940; called by muse, mutect2, varscan2
- APOA2 | c.270C>T p.F90= | Silent (SNP) | VAF 31/73 reads (42%) | catalogued as rs752976925, COSV57153940; called by muse, mutect2, varscan2
- CACNA1E | c.27C>A p.V9= | Silent (SNP) | VAF 16/75 reads (21%) | catalogued as COSV100701631, COSV62401831; called by muse, mutect2, varscan2
- CELSR3 | c.9555C>G p.L3185= | Silent (SNP) | VAF 14/29 reads (48%) | catalogued as COSV99373031; called by muse, mutect2, varscan2
- COL4A4 | c.3996G>A p.P1332= | Silent (SNP) | VAF 27/68 reads (40%) | catalogued as rs1051737695, COSV100306473; called by muse, mutect2, varscan2
- CXorf65 | c.120C>T p.I40= | Silent (SNP) | VAF 19/47 reads (40%) | catalogued as rs767725657, COSV99340105; called by muse, mutect2, varscan2
- DPYD | c.525G>T p.S175= | Silent (SNP) | VAF 26/54 reads (48%) | catalogued as rs6670886, COSV100928870; called by muse, mutect2, varscan2
- GRIN3A | c.2400C>T p.S800= | Silent (SNP) | VAF 38/96 reads (40%) | catalogued as COSV100701420; called by muse, mutect2, varscan2
- IGHV3-66 | c.168C>T p.V56= | Silent (SNP) | VAF 24/72 reads (33%) | catalogued as rs781785757; called by muse, mutect2, varscan2
- MAGI2 | c.1752G>A p.P584= | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as rs761029489, COSV100833779; called by muse, mutect2, varscan2
- MRC1 | c.138C>T p.T46= | Silent (SNP) | VAF 94/220 reads (43%) | catalogued as rs782739116, COSV100509561; called by muse, mutect2, varscan2
- PCDHB13 | c.1524G>A p.A508= | Silent (SNP) | VAF 56/194 reads (29%) | catalogued as rs782778861, COSV53398392; called by muse, mutect2
- PLXNA3 | c.3927G>A p.P1309= | Silent (SNP) | VAF 20/101 reads (20%) | catalogued as rs202128522, COSV63754528; called by muse, mutect2, varscan2
- TAF1 | c.822C>T p.Y274= (on ENST00000373790 / NM_138923.4; = p.Y295= on NM_004606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 26/77 reads (34%) | catalogued as rs775677773, COSV52107030; called by muse, mutect2, varscan2
- TENM3 | c.280C>A p.R94= | Silent (SNP) | VAF 50/101 reads (50%) | catalogued as COSV101304976; called by muse, mutect2, varscan2
- DLG3 | c.1145+701C>T | Intron (SNP) | VAF 35/102 reads (34%) | catalogued as COSV99529312; called by muse, mutect2, varscan2
